Somatic mutation profile of tumor specimen BA2464D (aliquot aq-BA2464D) from BEATAML1.0 case 2575, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute promyelocytic leukaemia, PML-RAR-alpha; Tissue or organ of origin: Bone marrow; Age at diagnosis: 40.2 years (14,668 days).
Specimen BA2464D: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 42bdb1e4-bf57-440c-89cf-b38cca33325e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2371D (Solid Tissue Normal), aliquot aq-BA2371D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fc0e2a80-27c1-4472-aaf9-78f67b06227a

The open-access MAF lists 16 somatic variants for this specimen: 9 protein-altering or splice-affecting, 3 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, Silent 3, Intron 2, Nonsense Mutation 2, 3'UTR 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACAT2 | c.962A>G p.N321S | Missense Mutation (SNP) | VAF 57/135 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs753538575; called by muse, mutect2, varscan2
- ADAMTS16 | c.784G>A p.E262K | Missense Mutation (SNP) | VAF 41/102 reads (40%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as rs766955434; called by muse, mutect2, varscan2
- CD1E | c.770G>C p.G257A | Missense Mutation (SNP) | VAF 34/82 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.9); catalogued as rs1253188460, COSV63773334; called by muse, varscan2
- DST | c.20051A>G p.D6684G (on ENST00000361203 / NM_001374722.1; = p.D4381G on NM_015548.5) | Missense Mutation (SNP) | VAF 70/180 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as rs945242853; called by muse, mutect2, varscan2
- WT1 | c.982G>T p.E328* | Nonsense Mutation (SNP) | VAF 77/231 reads (33%) | catalogued as CM0910181, COSV60067383, COSV60085585; called by muse, mutect2, varscan2
- DBNL | c.1150G>A p.A384T (on ENST00000448521 / NM_001014436.3; = p.A385T on NM_014063.7) | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.838); called by muse, mutect2, varscan2
- IKZF1 | c.238G>T p.E80* | Nonsense Mutation (SNP) | VAF 104/255 reads (41%) | called by muse, mutect2, varscan2
- PCNX3 | c.2350C>A p.L784M | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2
- ZNF599 | c.1297T>G p.C433G | Missense Mutation (SNP) | VAF 81/189 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.073); called by muse, mutect2, varscan2
- LGALS8 | c.126C>T p.D42= | Silent (SNP) | VAF 91/205 reads (44%) | catalogued as rs767712880; called by muse, mutect2, varscan2
- MLPH | c.1770C>G p.T590= | Silent (SNP) | VAF 103/246 reads (42%) | called by muse, mutect2, varscan2
- TTN | c.6819T>C p.L2273= (on ENST00000591111; = p.L2227= on NM_003319.4) | Silent (SNP) | VAF 107/220 reads (49%) | called by muse, mutect2, varscan2
- RGSL1 | c.301+491A>G | Intron (SNP) | VAF 51/91 reads (56%) | called by muse, mutect2, varscan2
- SRP19 | c.*11G>A | 3'UTR (SNP) | VAF 78/199 reads (39%) | called by muse, mutect2, varscan2
- TTLL12 | c.1576-298G>A | Intron (SNP) | VAF 69/152 reads (45%) | catalogued as rs965570843; called by muse, mutect2
- ZNF776 | c.-26C>A | 5'UTR (SNP) | VAF 5/47 reads (11%) | catalogued as rs1568473849; called by muse, mutect2
